Somatic mutation profile of tumor specimen MP2PRT-PAUTVD-TBP1-A (aliquot MP2PRT-PAUTVD-TBP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAUTVD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,715 days).
Specimen MP2PRT-PAUTVD-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4277a225-2119-4edb-a6a6-a445c2f18943.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUTVD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUTVD-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0f6427e-b709-4992-b9c9-6bc08447ed75

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARAF | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 74/722 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs923182352, COSV99283155; called by muse, mutect2, varscan2
- KL | c.2057C>T p.T686M | Missense Mutation (SNP) | VAF 30/375 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141695559; ClinVar: uncertain significance; called by muse, mutect2
- LAMA5 | c.6346C>T p.R2116C | Missense Mutation (SNP) | VAF 43/381 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs566603437, COSV53371270; called by muse, mutect2, varscan2
- LAMB2 | c.4684C>T p.R1562* | Nonsense Mutation (SNP) | VAF 59/485 reads (12%) | catalogued as rs774352333, CM042734, COSV59737532; called by muse, varscan2
- MAP1B | c.6935G>A p.R2312H | Missense Mutation (SNP) | VAF 31/352 reads (9%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.828); catalogued as rs148824055; called by muse, mutect2
- NPFFR2 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 60/553 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.446); catalogued as rs1428841227, COSV100440510; called by muse, mutect2, varscan2
- PPP1R11 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 73/329 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as rs769818708; called by muse, mutect2, varscan2
- TCTE1 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 91/399 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs771449698; called by muse, mutect2, varscan2
- ABCA6 | c.4148G>A p.G1383E | Missense Mutation (SNP) | VAF 27/377 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- FLAD1 | c.1667A>C p.N556T | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- OR10G2 | c.33C>T p.A11= | Silent (SNP) | VAF 29/274 reads (11%) | catalogued as rs563870255, COSV73390318; called by muse, mutect2, varscan2
- ZPLD1 | c.1119A>C p.A373= (on ENST00000466937 / NM_001329788.1; = p.A389= on NM_175056.2) | Silent (SNP) | VAF 50/339 reads (15%) | called by muse, mutect2, varscan2
- OPHN1 | chrX:68433716 G>A | 5'Flank (SNP) | VAF 32/394 reads (8%) | called by muse, mutect2
